Somatic mutation profile of tumor specimen HCM-BROD-0115-C16-86B (aliquot HCM-BROD-0115-C16-86B-01D-A85C-36) from HCMI case HCM-BROD-0115-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 43.5 years (15,886 days).
Specimen HCM-BROD-0115-C16-86B: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce86d0c5-bda3-4ef1-9c88-610b2f208153.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0115-C16-10B (Blood Derived Normal), aliquot HCM-BROD-0115-C16-10B-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe6815af-9165-4e05-8007-7b0dfb9bf9c7

The open-access MAF lists 110 somatic variants for this specimen: 86 protein-altering or splice-affecting, 19 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 19, Frame Shift Del 7, Intron 5, Nonsense Mutation 3, In Frame Del 2, Nonstop Mutation 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GAL3ST2 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 363/789 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372108744, CM1412990; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 259/546 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1384882995; called by muse, mutect2
- ADAMTS15 | c.1499T>G p.L500R | Missense Mutation (SNP) | VAF 209/443 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as rs1195459305; called by muse, mutect2, varscan2
- ANO4 | c.169G>T p.D57Y (on ENST00000392977 / NM_001286615.2; = p.D22Y on NM_178826.4) | Missense Mutation (SNP) | VAF 117/236 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs373885901; called by muse, mutect2, varscan2
- CACNA1G | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 150/457 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs184328705; called by muse, mutect2, varscan2
- CD209 | c.772T>G p.W258G | Missense Mutation (SNP) | VAF 154/321 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV52655421; called by muse, mutect2, varscan2
- CNKSR3 | c.1646G>T p.R549L | Missense Mutation (SNP) | VAF 132/270 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); catalogued as rs757670075; called by muse, mutect2, varscan2
- CNTN1 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 135/313 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61639394; called by muse, mutect2, varscan2
- COL7A1 | c.8272G>T p.V2758F | Missense Mutation (SNP) | VAF 12/269 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as rs1412140004; called by muse, mutect2
- CYP27C1 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 163/404 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs763255213; called by muse, mutect2, varscan2
- DVL1 | c.682C>T p.L228F | Missense Mutation (SNP) | VAF 221/511 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as rs752206428; called by muse, mutect2, varscan2
- FAM98A | c.1333G>C p.D445H | Missense Mutation (SNP) | VAF 36/792 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as rs1426901244; called by muse, mutect2
- GABRA1 | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 343/344 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV50099403; called by muse, mutect2, varscan2
- GSTO1 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 114/115 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1292504288; called by muse, mutect2, varscan2
- HSPH1 | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 148/326 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs368302544, COSV60713590; called by muse, mutect2, varscan2
- IGKV1-5 | c.9G>T p.M3I | Missense Mutation (SNP) | VAF 179/491 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs1357340047; called by muse, mutect2, varscan2
- LRP2 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 142/294 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs147295930, COSV55555420; called by muse, mutect2, varscan2
- METTL5 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 112/285 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs375682466, COSV53627940; called by muse, mutect2, varscan2
- NCOR2 | c.2024A>G p.K675R | Missense Mutation (SNP) | VAF 156/332 reads (47%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.99); catalogued as rs760401324; called by muse, varscan2
- NSD3 | c.2138C>T p.S713F | Missense Mutation (SNP) | VAF 200/400 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.305); catalogued as rs1456616250; called by muse, mutect2, varscan2
- OLFM3 | c.632G>A p.R211H (on ENST00000338858 / NM_001288821.1; = p.R191H on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/248 reads (45%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs776719691, COSV58801848, COSV58804479; called by muse, mutect2, varscan2
- OSM | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 266/614 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.224); catalogued as rs199892388; called by mutect2, varscan2
- PCDHGA5 | c.1676C>T p.T559M | Missense Mutation (SNP) | VAF 502/505 reads (99%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.046); catalogued as rs760966863, COSV54003473; called by muse, mutect2, varscan2
- PNPLA8 | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 133/322 reads (41%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs769232930; called by muse, mutect2, varscan2
- RALBP1 | c.1934C>A p.S645* | Nonsense Mutation (SNP) | VAF 400/592 reads (68%) | catalogued as COSV50034210; called by muse, mutect2, varscan2
- RYR2 | c.12116G>C p.G4039A | Missense Mutation (SNP) | VAF 160/575 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.053); catalogued as COSV100768908; called by muse, mutect2, varscan2
- RYR3 | c.10099G>A p.V3367M (on ENST00000389232; = p.V3368M on NM_001036.6) | Missense Mutation (SNP) | VAF 180/416 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761453884, COSV66777080; called by muse, varscan2
- TMCO6 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 303/305 reads (99%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs753691038; called by muse, mutect2, varscan2
- TTN | c.74079G>T p.W24693C (on ENST00000591111; = p.W17269C on NM_003319.4) | Missense Mutation (SNP) | VAF 18/440 reads (4%) | PolyPhen probably damaging (0.999); catalogued as COSV60195965; called by muse, mutect2
- ZC2HC1C | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 203/432 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs780067829; called by muse, mutect2, varscan2
- ZFHX3 | c.1646C>G p.S549C | Missense Mutation (SNP) | VAF 196/442 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV51741539; called by muse, mutect2, varscan2
- ZNF804B | c.919C>G p.H307D | Missense Mutation (SNP) | VAF 104/278 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100302413; called by muse, mutect2, varscan2
- ANK2 | c.2177A>G p.K726R | Missense Mutation (SNP) | VAF 113/224 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- APLF | c.476_486del p.P159Rfs*6 | Frame Shift Del (DEL) | VAF 109/252 reads (43%) | called by mutect2, pindel, varscan2
- AQP6 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 299/611 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ASH1L | c.7574A>T p.Y2525F (on ENST00000368346 / NM_001366177.2; = p.Y2520F on NM_018489.3) | Missense Mutation (SNP) | VAF 119/345 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BPTF | c.7128T>G p.H2376Q | Missense Mutation (SNP) | VAF 224/761 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRINP1 | c.2108_2109dup p.N704Lfs*22 | Frame Shift Ins (INS) | VAF 172/638 reads (27%) | called by mutect2, pindel, varscan2
- C19orf81 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 257/579 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CCL21 | c.382_398del p.S128Afs*5 | Frame Shift Del (DEL) | VAF 194/207 reads (94%) | called by mutect2, pindel, varscan2
- CCN2 | c.772C>A p.R258S | Missense Mutation (SNP) | VAF 121/224 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTNNB1 | c.2346A>C p.*782Yext*4 | Nonstop Mutation (SNP) | VAF 257/258 reads (100%) | called by muse, mutect2, varscan2
- DBP | c.572C>G p.P191R | Missense Mutation (SNP) | VAF 165/362 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DOCK10 | c.6236C>A p.A2079D | Missense Mutation (SNP) | VAF 137/335 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DYRK3 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 405/405 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- EDARADD | c.430_435del p.S144_K145del (on ENST00000334232 / NM_145861.4; = p.S134_K135del on NM_080738.4) | In Frame Del (DEL) | VAF 166/396 reads (42%) | called by mutect2, pindel, varscan2
- EIF4E1B | c.278C>A p.T93N | Missense Mutation (SNP) | VAF 210/449 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- EPB41L1 | c.56_72del p.P19Rfs*22 | Frame Shift Del (DEL) | VAF 309/523 reads (59%) | called by pindel, varscan2
- FABP12 | c.247A>C p.S83R | Missense Mutation (SNP) | VAF 128/234 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- FAT4 | c.2642_2688del p.I881Nfs*25 | Frame Shift Del (DEL) | VAF 82/327 reads (25%) | called by mutect2, pindel, varscan2
- FIBCD1 | c.89A>C p.Y30S | Missense Mutation (SNP) | VAF 214/1013 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- HDGF | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 211/700 reads (30%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.048); called by muse, mutect2
- IGDCC4 | c.1973T>C p.I658T | Missense Mutation (SNP) | VAF 297/608 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- IL5RA | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 225/226 reads (100%) | called by muse, mutect2, varscan2
- ISY1-RAB43 | c.65A>T p.E22V | Missense Mutation (SNP) | VAF 117/499 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.373); called by muse, mutect2
- LHX1 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 867/1307 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- LIMCH1 | c.1272A>C p.R424S | Missense Mutation (SNP) | VAF 99/234 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MAZ | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 150/477 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MCOLN2 | c.879T>G p.F293L | Missense Mutation (SNP) | VAF 277/278 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MEP1B | c.134G>C p.G45A | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MPEG1 | c.149G>C p.G50A | Missense Mutation (SNP) | VAF 191/434 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MPP3 | c.929G>A p.S310N | Missense Mutation (SNP) | VAF 243/754 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC16 | c.36962A>G p.E12321G | Missense Mutation (SNP) | VAF 143/352 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NASP | c.436C>G p.Q146E | Missense Mutation (SNP) | VAF 144/325 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NUP214 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 189/789 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- OLFML1 | c.1099A>G p.S367G | Missense Mutation (SNP) | VAF 195/413 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- OLFML2B | c.1844_1864del p.Q615_F622delinsL | In Frame Del (DEL) | VAF 156/713 reads (22%) | called by mutect2, pindel, varscan2
- OSBPL1A | c.207+1G>A p.X69_splice | Splice Site (SNP) | VAF 137/275 reads (50%) | called by muse, mutect2, varscan2
- PBRM1 | c.2972A>T p.K991I | Missense Mutation (SNP) | VAF 112/113 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- PNPLA6 | c.2094_2097+1del | Frame Shift Del (DEL) | VAF 125/315 reads (40%) | called by mutect2, pindel, varscan2
- PTGS1 | c.1369A>C p.M457L | Missense Mutation (SNP) | VAF 211/638 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RANBP2 | c.6144G>T p.E2048D | Missense Mutation (SNP) | VAF 229/552 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RC3H2 | c.439G>C p.G147R | Missense Mutation (SNP) | VAF 397/595 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- S1PR3 | c.445A>C p.N149H | Missense Mutation (SNP) | VAF 309/624 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SH3YL1 | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 134/294 reads (46%) | called by muse, mutect2, varscan2
- SLC18A1 | c.176C>A p.S59Y | Missense Mutation (SNP) | VAF 184/384 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTA1 | c.3736G>T p.A1246S | Missense Mutation (SNP) | VAF 267/417 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- TACC2 | c.5110del p.E1704Kfs*8 | Frame Shift Del (DEL) | VAF 247/625 reads (40%) | called by mutect2, pindel, varscan2
- TBC1D22B | c.274_287del p.V92Cfs*37 | Frame Shift Del (DEL) | VAF 168/369 reads (46%) | called by mutect2, pindel, varscan2
- TDRKH | c.1551T>G p.D517E | Missense Mutation (SNP) | VAF 147/479 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNS2 | c.3078C>G p.S1026R (on ENST00000314250 / NM_170754.4; = p.S1036R on NM_015319.2) | Missense Mutation (SNP) | VAF 420/837 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TTLL11 | c.2302C>A p.P768T | Missense Mutation (SNP) | VAF 314/460 reads (68%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.011); called by mutect2, varscan2
- UNC79 | c.1395T>G p.H465Q (on ENST00000393151 / NM_001346218.2; = p.H288Q on NM_020818.5) | Missense Mutation (SNP) | VAF 258/268 reads (96%) | SIFT tolerated (0.31); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- WRAP73 | c.1363C>G p.Q455E | Missense Mutation (SNP) | VAF 313/314 reads (100%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF131 | c.1550C>A p.P517Q (on ENST00000509156 / NM_001330707.2; = p.P483Q on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 135/300 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF804A | c.3275C>T p.S1092F | Missense Mutation (SNP) | VAF 149/345 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGEF18 | c.156G>A p.P52= | Silent (SNP) | VAF 336/688 reads (49%) | called by muse, mutect2
- CYTL1 | c.174G>T p.L58= | Silent (SNP) | VAF 133/490 reads (27%) | called by muse, mutect2, varscan2
- EPB41L1 | c.78C>T p.A26= | Silent (SNP) | VAF 346/548 reads (63%) | catalogued as rs372761608; called by muse, varscan2
- EVC | c.2814C>T p.P938= | Silent (SNP) | VAF 137/451 reads (30%) | called by muse, mutect2, varscan2
- F9 | c.1302G>A p.E434= | Silent (SNP) | VAF 15/267 reads (6%) | called by muse, mutect2
- FCRLB | c.192C>A p.G64= | Silent (SNP) | VAF 224/794 reads (28%) | catalogued as rs777301346, COSV100396075; called by muse, mutect2, varscan2
- FSIP2 | c.1179T>C p.N393= | Silent (SNP) | VAF 88/208 reads (42%) | called by muse, mutect2, varscan2
- IQCA1L | c.2407T>C p.L803= | Silent (SNP) | VAF 224/459 reads (49%) | called by muse, mutect2, varscan2
- IQCA1L | c.1980G>T p.L660= | Silent (SNP) | VAF 223/432 reads (52%) | called by muse, mutect2, varscan2
- ISY1-RAB43 | c.63A>G p.E21= | Silent (SNP) | VAF 119/509 reads (23%) | catalogued as rs1276849268; called by muse, mutect2
- KMT2D | c.4932C>T p.D1644= | Silent (SNP) | VAF 186/400 reads (47%) | called by muse, mutect2, varscan2
- LNX2 | c.963C>T p.G321= | Silent (SNP) | VAF 238/463 reads (51%) | called by muse, mutect2, varscan2
- MFAP1 | c.249C>T p.D83= | Silent (SNP) | VAF 94/360 reads (26%) | called by muse, mutect2, varscan2
- MUC16 | c.312G>T p.S104= | Silent (SNP) | VAF 174/337 reads (52%) | catalogued as rs375785587; called by muse, mutect2, varscan2
- PDE4A | c.945A>G p.R315= (on ENST00000380702 / NM_001111307.2; = p.R76= on NM_006202.3) | Silent (SNP) | VAF 185/433 reads (43%) | called by muse, mutect2, varscan2
- PLEKHA4 | c.2121G>A p.P707= | Silent (SNP) | VAF 293/633 reads (46%) | called by muse, mutect2, varscan2
- PLP1 | c.132A>G p.E44= | Silent (SNP) | VAF 258/274 reads (94%) | called by muse, mutect2, varscan2
- PPP4R1 | c.1416T>G p.L472= (on ENST00000400556 / NM_001042388.3; = p.L455= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 392/621 reads (63%) | called by muse, mutect2
- SFTPA2 | c.138G>A p.G46= | Silent (SNP) | VAF 195/435 reads (45%) | catalogued as rs746354270; called by muse, mutect2, varscan2
- CCDC74B | c.295+305G>A | Intron (SNP) | VAF 220/484 reads (45%) | catalogued as rs1394222364; called by muse, mutect2, varscan2
- KCNQ5 | c.1248-3571_1248-3543del | Intron (DEL) | VAF 58/65 reads (89%) | called by mutect2, pindel, varscan2
- NKX6-3 | c.553-562C>G | Intron (SNP) | VAF 246/524 reads (47%) | called by muse, mutect2, varscan2
- PHKB | c.76+2516G>A | Intron (SNP) | VAF 102/451 reads (23%) | catalogued as rs1326588225; called by muse, mutect2, varscan2
- PHKB | c.76+2517C>T | Intron (SNP) | VAF 94/418 reads (22%) | called by muse, varscan2
